Somatic mutation profile of tumor specimen TCGA-44-7671-01A (aliquot TCGA-44-7671-01A-11D-2063-08) from TCGA case TCGA-44-7671, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.4 years (23,538 days).
Specimen TCGA-44-7671-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaad93c1-4b61-4033-9369-77b43139fcec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-7671-10A (Blood Derived Normal), aliquot TCGA-44-7671-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5c91e83-ea12-440d-a64c-0536b76fc20a

The open-access MAF lists 253 somatic variants for this specimen: 190 protein-altering or splice-affecting, 55 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 159, Silent 55, Nonsense Mutation 13, Frame Shift Del 11, Splice Site 4, Intron 3, 5'Flank 3, In Frame Del 2, Splice Region 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 10/16 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SNRPD3 | c.286G>C p.G96R | Missense Mutation (SNP) | VAF 27/70 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV53182727, COSV53183815, COSV99307458; called by muse, mutect2, varscan2
- SNRPD3 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV53183301, COSV53184122; called by muse, mutect2, varscan2
- ABCA13 | c.14536C>G p.L4846V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68950092; called by muse, mutect2, varscan2
- ADAM2 | c.1225A>T p.I409F | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV55867066; called by muse, mutect2, varscan2
- ADGRG4 | c.5887G>T p.A1963S | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54964584; called by muse, mutect2, varscan2
- AKAP1 | c.2503G>A p.D835N | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs1269592958, COSV61805535; called by muse, mutect2, varscan2
- APOBEC3G | c.612C>A p.F204L | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV68470110, COSV68470781; called by muse, mutect2, varscan2
- ARHGAP11A | c.2062A>G p.I688V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV55706899; called by muse, mutect2, varscan2
- ARHGEF10 | c.1567A>G p.S523G (on ENST00000398564; = p.S498G on NM_014629.4) | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV50670398; called by muse, mutect2, varscan2
- ARHGEF11 | c.2033G>T p.R678M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV59357741; called by muse, mutect2, varscan2
- ATR | c.2391A>T p.E797D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as COSV63390838; called by muse, mutect2, varscan2
- BMPER | c.577-1G>T p.X193_splice | Splice Site (SNP) | VAF 28/146 reads (19%) | catalogued as COSV99779239; called by muse, mutect2, varscan2
- BMPER | c.577G>T p.G193* | Nonsense Mutation (SNP) | VAF 34/156 reads (22%) | catalogued as COSV99779242; called by muse, mutect2, varscan2
- BNIP5 | c.425C>G p.P142R | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); catalogued as COSV71325807; called by muse, mutect2, varscan2
- BOC | c.1243C>A p.P415T | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as COSV56356637; called by muse, mutect2, varscan2
- BRINP3 | c.2047C>A p.L683M | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100819615, COSV66513180; called by muse, mutect2, varscan2
- CALCR | c.1239+1G>T p.X413_splice (on ENST00000649521 / NM_001164737.2; = p.X397_splice on NM_001742.4) | Splice Site (SNP) | VAF 31/82 reads (38%) | catalogued as COSV64011266; called by muse, mutect2, varscan2
- CAMSAP1 | c.2720G>A p.R907H | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747762999, COSV56727440; called by muse, mutect2, varscan2
- CASP3 | c.343G>T p.V115F | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV57725667; called by muse, mutect2, varscan2
- CCDC39 | c.879T>A p.C293* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV56491748; called by muse, mutect2, varscan2
- CETN1 | c.91C>A p.Q31K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV59122025; called by muse, mutect2, varscan2
- CFC1 | c.159G>T p.W53C | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as COSV99383453; called by muse, mutect2, varscan2
- CHD7 | c.7903A>T p.K2635* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV71113758; called by muse, mutect2, varscan2
- CHRNA3 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV58775489; called by muse, mutect2, varscan2
- CNTN5 | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV54347808; called by muse, mutect2, varscan2
- CNTNAP5 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs768609837; called by muse, mutect2
- DCDC1 | c.927T>G p.H309Q | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1347786247, COSV60855600; called by muse, mutect2, varscan2
- DCLK3 | c.1091A>G p.D364G | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69364426; called by muse, mutect2, varscan2
- DDX42 | c.2486G>A p.S829N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1209695717, COSV63790513, COSV63791113; called by muse, mutect2, varscan2
- DIP2A | c.2658G>T p.Q886H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as rs759036409, COSV59485217; called by muse, mutect2, varscan2
- DNAH9 | c.13192A>G p.I4398V | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV52371637; called by muse, mutect2, varscan2
- DRD2 | c.115A>T p.T39S | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV60761957; called by muse, mutect2, varscan2
- EIF2B3 | c.1237G>T p.A413S | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV64518443; called by muse, mutect2, varscan2
- EMP3 | c.398del p.G133Afs*? | Frame Shift Del (DEL) | VAF 39/80 reads (49%) | catalogued as rs1275937883; called by mutect2, pindel, varscan2
- ERICH3 | c.1564C>G p.Q522E | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV58615709; called by muse, mutect2, varscan2
- FAM153A | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.148); catalogued as COSV62363399; called by muse, mutect2, varscan2
- FBN2 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as COSV52539144; called by muse, mutect2, varscan2
- FBXO15 | c.817A>T p.N273Y | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54047841; called by muse, mutect2, varscan2
- FCRL2 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV63838074; called by muse, mutect2, varscan2
- FHOD3 | c.3032A>T p.E1011V (on ENST00000359247 / NM_001281739.3; = p.E1028V on NM_025135.5) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57185541; called by muse, mutect2, varscan2
- FLRT2 | c.157A>T p.S53C | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58141774, COSV58148520; called by muse, mutect2, varscan2
- FNIP1 | c.210A>G p.I70M | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs1427336447, COSV57199696; called by muse, mutect2, varscan2
- FURIN | c.829G>T p.G277W | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51579051; called by muse, mutect2, varscan2
- GABRA2 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV62918705; called by muse, mutect2, varscan2
- GADD45G | c.212A>G p.D71G | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53000350; called by muse, mutect2, varscan2
- GAL3ST3 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as rs776334488, COSV100360772; called by muse, mutect2, varscan2
- GALNT15 | c.540-1G>A p.X180_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as COSV60219195; called by muse, mutect2, varscan2
- GBP4 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.315); catalogued as rs375773007; called by muse, mutect2, varscan2
- GIMAP8 | c.1378G>T p.G460W | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563288551, COSV56231124; called by muse, mutect2, varscan2
- GPR148 | c.187A>T p.T63S | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.231); catalogued as COSV59309245; called by muse, mutect2, varscan2
- GRM5 | c.1214A>G p.Y405C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59624279; called by muse, mutect2, varscan2
- GSTO2 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as COSV58538417; called by muse, mutect2, varscan2
- HMCN1 | c.2042G>T p.C681F | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54932799; called by muse, mutect2, varscan2
- HTR1E | c.943G>T p.G315C | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs1409038983, COSV59510382; called by muse, mutect2, varscan2
- IL2 | c.187A>T p.K63* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV56986566; called by muse, mutect2, varscan2
- IL7R | c.1151C>A p.S384Y | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV57407168, COSV57411528; called by muse, mutect2, varscan2
- INPP5J | c.1805G>T p.G602V (on ENST00000331075 / NM_001284285.2; = p.G234V on NM_001002837.2) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58514904; called by muse, mutect2, varscan2
- INSL5 | c.360G>T p.L120F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV58788557; called by muse, varscan2
- KCTD16 | c.743T>G p.V248G | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV72580313; called by muse, mutect2, varscan2
- KEAP1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV50264906; called by muse, mutect2, varscan2
- KIF21A | c.2003A>T p.Q668L (on ENST00000361418 / NM_001378440.1; = p.Q655L on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62776806; called by muse, mutect2, varscan2
- KLHL1 | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64780623; called by muse, mutect2, varscan2
- KREMEN2 | c.71C>A p.S24* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV53557215; called by mutect2, varscan2
- KRTAP6-1 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 39/184 reads (21%) | PolyPhen probably damaging (0.998); catalogued as COSV58168774; called by muse, mutect2, varscan2
- LAMA3 | c.5135G>T p.G1712V (on ENST00000313654 / NM_198129.4; = p.G103V on NM_000227.6) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52541507; called by muse, mutect2, varscan2
- LDHAL6B | c.418C>A p.L140I | Missense Mutation (SNP) | VAF 77/156 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.061); catalogued as COSV55693723; called by muse, mutect2, varscan2
- LMBRD2 | c.1108A>T p.N370Y | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV56952191; called by muse, mutect2, varscan2
- MCM4 | c.1712G>T p.C571F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50630845; called by muse, mutect2, varscan2
- MET | c.1979C>G p.T660R | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.269); catalogued as COSV59267295; called by muse, mutect2, varscan2
- MGA | c.8234A>T p.K2745I (on ENST00000219905 / NM_001164273.1; = p.K2536I on NM_001080541.2) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV54961293; called by muse, mutect2, varscan2
- MSH5 | c.1642C>A p.R548S | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.055); catalogued as COSV65211122; called by muse, mutect2, varscan2
- MTMR14 | c.1293G>A p.L431= | Splice Region (SNP) | VAF 5/80 reads (6%) | catalogued as COSV56007096; called by muse, mutect2
- MTUS2 | c.3487C>A p.H1163N (on ENST00000612955 / NM_001366650.1; = p.H142N on NM_015233.6) | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); catalogued as COSV60158565; called by muse, mutect2, varscan2
- MUC16 | c.40654A>C p.T13552P | Missense Mutation (SNP) | VAF 63/98 reads (64%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as rs868660041, COSV66695760; called by muse, mutect2, varscan2
- MUC16 | c.8934del p.T2979Lfs*26 | Frame Shift Del (DEL) | VAF 61/130 reads (47%) | catalogued as COSV67485802; called by mutect2, pindel, varscan2
- MUC5B | c.9104C>T p.T3035I | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.908); catalogued as rs774387660, COSV71594682; called by muse, mutect2, varscan2
- MVP | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as COSV62423201; called by muse, mutect2, varscan2
- NAF1 | c.50A>T p.N17I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as COSV56805698; called by muse, mutect2, varscan2
- NCKAP5 | c.603G>C p.L201F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV58468995; called by muse, mutect2, varscan2
- NOX5 | c.1774G>A p.G592S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs145431252; called by muse, mutect2, varscan2
- NPY1R | c.489G>T p.W163C | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV56715982; called by muse, mutect2, varscan2
- NUF2 | c.854G>T p.C285F | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV54846409; called by muse, mutect2, varscan2
- NUP98 | c.4313C>A p.P1438Q (on ENST00000359171 / NM_001365126.1; = p.P1421Q on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61437498; called by muse, mutect2, varscan2
- OBSL1 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1315248528, COSV54728415; called by muse, mutect2, varscan2
- OR2L13 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV63549646, COSV63550162; called by muse, mutect2, varscan2
- OR4C12 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); catalogued as COSV58860903; called by muse, mutect2, varscan2
- OR4F15 | c.268A>C p.K90Q | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV59970061; called by muse, mutect2, varscan2
- OR51D1 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62914734; called by muse, mutect2, varscan2
- OR5AC2 | c.864C>G p.N288K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100684559, COSV62280038; called by muse, mutect2, varscan2
- OR5F1 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV53548289; called by muse, mutect2, varscan2
- OR5M3 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56566284, COSV56568170; called by muse, mutect2, varscan2
- PAIP1 | c.883A>T p.I295F | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV59087228; called by muse, mutect2
- PCDH18 | c.2756C>A p.T919K | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139751813, COSV61271520; called by muse, mutect2, varscan2
- PCDHA7 | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.632); catalogued as COSV65346741; called by muse, mutect2, varscan2
- PCDHB11 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV61313675; called by muse, mutect2, varscan2
- PCDHB3 | c.737T>A p.L246H | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.94); catalogued as COSV50616810; called by muse, mutect2, varscan2
- PCDHB3 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 128/263 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV50586567; called by muse, mutect2, varscan2
- PCDHGA2 | c.1705A>T p.T569S | Missense Mutation (SNP) | VAF 111/284 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as COSV53958508, COSV54013483; called by muse, mutect2, varscan2
- PCDHGC5 | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as COSV52764697; called by muse, mutect2, varscan2
- PELI2 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151092148, COSV50715047; called by muse, mutect2, varscan2
- PLA2G4C | c.443G>T p.R148I | Missense Mutation (SNP) | VAF 50/70 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62787451; called by muse, mutect2, varscan2
- PLCG1 | c.3029G>A p.R1010H | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868557349, COSV54818084, COSV54822887; called by muse, mutect2
- PMF1-BGLAP | c.368+1G>T p.X123_splice | Splice Site (SNP) | VAF 52/146 reads (36%) | catalogued as COSV60772185; called by muse, mutect2, varscan2
- PPIP5K1 | c.4043A>T p.K1348M (on ENST00000396923; = p.K1323M on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV55811827; called by muse, mutect2, varscan2
- PPP2R2D | c.321G>A p.W107* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV70779664; called by muse, mutect2, varscan2
- PPP2R5B | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51212424; called by muse, mutect2, varscan2
- PRAMEF4 | c.500C>A p.T167N | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs780111641, COSV99339626; called by muse, mutect2, varscan2
- PRC1 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.023); catalogued as COSV62696339; called by muse, varscan2
- PRDM9 | c.2672G>T p.R891M | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV57011816; called by muse, mutect2, varscan2
- PRKACG | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1451893780, COSV55256044; called by muse, mutect2, varscan2
- PRSS38 | c.296C>A p.A99E | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64541070, COSV64541613; called by muse, mutect2, varscan2
- PTCHD4 | c.1981G>C p.V661L | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV59794783; called by muse, mutect2, varscan2
- PTPN14 | c.2003G>C p.R668P | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.547); catalogued as COSV65287395; called by muse, mutect2, varscan2
- PTPRD | c.5154G>T p.Q1718H | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV61974878, COSV61991614; called by muse, mutect2, varscan2
- PTPRD | c.3301G>T p.A1101S | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs1405369086, COSV61974891; called by muse, mutect2, varscan2
- PTPRG | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as rs866875275, COSV55659184; called by muse, mutect2, varscan2
- RASIP1 | c.2867G>A p.G956E | Missense Mutation (SNP) | VAF 113/161 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV55807724; called by muse, mutect2, varscan2
- RGS10 | c.359A>G p.Q120R (on ENST00000369101; = p.Q114R on NM_002925.3) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.849); catalogued as COSV64862534; called by muse, mutect2, varscan2
- RNASE3 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs765777874, COSV58959861; called by muse, mutect2, varscan2
- RNF31 | c.2440G>C p.E814Q | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.963); catalogued as COSV60728215; called by muse, mutect2, varscan2
- RP1L1 | c.4262C>A p.S1421Y | Missense Mutation (SNP) | VAF 181/574 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as rs769465248, COSV66759177; called by muse, mutect2, varscan2
- RYR2 | c.10372C>T p.R3458W | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1338386727, COSV63692125, COSV63716462; called by muse, mutect2, varscan2
- RYR2 | c.10373G>C p.R3458P | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV100768952, COSV100771942; called by muse, mutect2, varscan2
- RYR2 | c.12826G>T p.V4276L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV63686088; called by muse, mutect2, varscan2
- SCFD2 | c.355C>G p.P119A | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.444); catalogued as COSV66376205; called by muse, mutect2, varscan2
- SGO2 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV63417372; called by muse, mutect2, varscan2
- SHISAL1 | c.569C>A p.P190Q | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV66988656; called by muse, mutect2, varscan2
- SLC12A7 | c.2644G>T p.A882S | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV53761502; called by muse, mutect2, varscan2
- SLC18A2 | c.548C>A p.A183D | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV100041458; called by muse, mutect2, varscan2
- SLC34A1 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758454383, CM153739, COSV53692828; called by muse, mutect2, varscan2
- SLC39A12 | c.990G>C p.K330N | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101069920; called by muse, mutect2, varscan2
- SLC39A12 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 25/90 reads (28%) | catalogued as COSV101069922, COSV66202480; called by muse, mutect2, varscan2
- SLC39A6 | c.902G>T p.R301I | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV52370958; called by muse, mutect2, varscan2
- SLCO3A1 | c.848T>G p.F283C | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59235974; called by muse, mutect2, varscan2
- SLIT3 | c.336G>T p.E112D | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV60629290; called by muse, mutect2, varscan2
- SLITRK1 | c.1838G>T p.S613I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as COSV65676915; called by muse, mutect2, varscan2
- SLITRK2 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV59428056, COSV59428576, COSV59429530; called by muse, mutect2, varscan2
- SMTNL1 | c.1273G>A p.V425M (on ENST00000399154; = p.V462M on NM_001105565.2) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.498); catalogued as COSV54703758; called by muse, mutect2, varscan2
- SNX7 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60271318; called by muse, mutect2, varscan2
- SOCS6 | c.1004A>T p.H335L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV67547005; called by muse, mutect2, varscan2
- SPRY2 | c.572A>T p.Y191F | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.973); catalogued as COSV65701712; called by muse, mutect2, varscan2
- SPTBN5 | c.2672G>T p.R891L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV58026777; called by muse, mutect2, varscan2
- SPTLC3 | c.599A>T p.H200L | Missense Mutation (SNP) | VAF 83/205 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV65467982; called by muse, mutect2, varscan2
- SRSF2 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.089); catalogued as COSV57975000; called by muse, mutect2
- STARD8 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV99366488; called by muse, mutect2, varscan2
- STK11 | c.784A>T p.K262* | Nonsense Mutation (SNP) | VAF 13/18 reads (72%) | catalogued as COSV58827527; called by muse, mutect2, varscan2
- SUCO | c.3516G>C p.Q1172H | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.145); catalogued as COSV55270064; called by muse, mutect2, varscan2
- SULT1C3 | c.888C>A p.S296R | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV61254415; called by muse, mutect2, varscan2
- SYNE2 | c.16869C>A p.S5623R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as COSV100647137; called by muse, mutect2, varscan2
- SYNE2 | c.16870C>T p.L5624F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100647141; called by muse, mutect2, varscan2
- TAS2R60 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60331824; called by muse, mutect2, varscan2
- TBC1D21 | c.628C>A p.L210I | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1281313049, COSV55996444; called by muse, mutect2, varscan2
- TENT5D | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs199636557, COSV57638732; called by muse, mutect2, varscan2
- TFAP2C | c.541G>T p.D181Y | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52372837, COSV99571697; called by muse, mutect2, varscan2
- TFAP2D | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as rs748424019, COSV50448505; called by muse, mutect2, varscan2
- TFDP1 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 32/93 reads (34%) | catalogued as COSV64739463; called by muse, mutect2, varscan2
- TPTE | c.691A>T p.T231S (on ENST00000618007 / NM_199261.4; = p.T213S on NM_199259.4) | Missense Mutation (SNP) | VAF 86/592 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as rs1256015892; called by muse, mutect2, varscan2
- TRPC6 | c.272G>C p.R91P | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100723517, COSV60255510; called by muse, mutect2, varscan2
- TRPC6 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs200186406; called by muse, mutect2, varscan2
- TRPM3 | c.5002C>T p.R1668W (on ENST00000357533 / NM_001366142.2; = p.R1523W on NM_020952.6) | Missense Mutation (SNP) | VAF 143/225 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.719); catalogued as rs41287375; called by muse, mutect2, varscan2
- TRPV5 | c.538C>G p.R180G | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV54684214, COSV54688980; called by muse, mutect2, varscan2
- TSC22D1 | c.736A>T p.S246C | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV71776178; called by muse, mutect2, varscan2
- TSLP | c.43A>T p.R15W | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61292281; called by muse, mutect2, varscan2
- TTN | c.23069G>T p.R7690L (on ENST00000591111; = p.R6763L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/129 reads (25%) | PolyPhen benign (0.13); catalogued as COSV60284308; called by muse, mutect2, varscan2
- TVP23C | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV56672513; called by muse, mutect2, varscan2
- UNC13C | c.4777C>G p.P1593A | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as COSV52914204; called by muse, mutect2, varscan2
- UPP1 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1365269449, COSV57978381; called by muse, mutect2, varscan2
- VIM | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 33/75 reads (44%) | catalogued as COSV56407400; called by muse, mutect2, varscan2
- ZEB1 | c.2564A>C p.E855A | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.76); catalogued as COSV58052429; called by muse, mutect2, varscan2
- ZFHX4 | c.3745C>T p.P1249S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51489927; called by muse, mutect2, varscan2
- ZFHX4 | c.7694C>A p.S2565Y | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV51489945, COSV99257845; called by muse, mutect2, varscan2
- ZFHX4 | c.8719C>G p.P2907A | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51489962, COSV51498739, COSV99266118; called by muse, mutect2, varscan2
- ZNF607 | c.1915C>A p.H639N | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1223862093, COSV62206193; called by muse, mutect2, varscan2
- ZNF804A | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 39/74 reads (53%) | catalogued as COSV56467062; called by muse, mutect2, varscan2
- ZNF835 | c.119T>A p.V40E | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV73379702; called by muse, mutect2, varscan2
- ASXL3 | c.1940del p.T647Kfs*30 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- C1QA | c.374del p.P125Qfs*157 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- CT45A1 | c.121G>T p.G41* | Nonsense Mutation (SNP) | VAF 36/409 reads (9%) | called by muse, mutect2
- DCAF4L2 | c.1099del p.A367Pfs*46 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | called by mutect2, pindel, varscan2
- FASTK | c.1366_1368del p.P456del | In Frame Del (DEL) | VAF 8/59 reads (14%) | called by pindel, varscan2
- GDF2 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IL36G | c.444del p.I149Sfs*3 | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | called by mutect2, pindel, varscan2
- MROH9 | c.546_567del p.D183Hfs*38 | Frame Shift Del (DEL) | VAF 109/378 reads (29%) | called by mutect2, pindel, varscan2
- NDST4 | c.175_176del p.P59Ifs*2 | Frame Shift Del (DEL) | VAF 32/78 reads (41%) | called by mutect2, pindel*, varscan2*
- NSD1 | c.750del p.A251Qfs*10 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | called by pindel, varscan2
- RRP1B | c.2202_2216del p.S735_V739del | In Frame Del (DEL) | VAF 13/27 reads (48%) | called by mutect2, pindel
- SNX1 | c.1292_1298del p.R431Pfs*28 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- TBX2 | c.1498C>A p.P500T | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ZNF148 | c.625del p.I209Yfs*26 | Frame Shift Del (DEL) | VAF 19/65 reads (29%) | called by mutect2, pindel, varscan2
- ADAMTS14 | c.349C>T p.L117= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV64605591; called by muse, mutect2, varscan2
- ANKRD35 | c.1329A>G p.Q443= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV62911368; called by muse, mutect2, varscan2
- ANKRD55 | c.210T>C p.S70= | Silent (SNP) | VAF 45/166 reads (27%) | catalogued as rs1485681297, COSV61949876; called by muse, mutect2, varscan2
- ATP11A | c.66C>T p.D22= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as rs755266989, COSV52121269; called by muse, mutect2, varscan2
- BPI | c.153G>A p.Q51= (on ENST00000262865; = p.Q47= on NM_001725.3) | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as rs1198490806, COSV53407857; called by muse, mutect2, varscan2
- CLPTM1 | c.633G>T p.L211= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV61612791; called by muse, mutect2, varscan2
- CNOT9 | c.483A>C p.T161= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV55301560; called by muse, mutect2, varscan2
- COL6A6 | c.1222C>A p.R408= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV62016903, COSV62034742; called by muse, mutect2, varscan2
- CPXM1 | c.2184G>T p.R728= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV66046531; called by muse, mutect2, varscan2
- CSMD1 | c.2238G>T p.V746= (on ENST00000520002; = p.V745= on NM_033225.6) | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs577019255, COSV59371053; called by muse, mutect2, varscan2
- DCANP1 | c.225C>A p.T75= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV72345902; called by muse, mutect2, varscan2
- DDX25 | c.462G>A p.V154= | Silent (SNP) | VAF 71/173 reads (41%) | catalogued as rs571626979, COSV54992167; called by muse, mutect2, varscan2
- DPP3 | c.1726C>T p.L576= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs567600069, COSV64757799; called by muse, mutect2, varscan2
- ELN | c.1059T>A p.V353= | Silent (SNP) | VAF 45/72 reads (63%) | catalogued as COSV52714446; called by muse, mutect2, varscan2
- FRY | c.1932A>C p.A644= | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as COSV66577492; called by muse, mutect2, varscan2
- GLT8D2 | c.345G>A p.P115= | Silent (SNP) | VAF 67/111 reads (60%) | catalogued as rs564549205, COSV62562845; called by muse, mutect2, varscan2
- GOLIM4 | c.54G>T p.L18= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs917696620, COSV58331490; called by muse, mutect2, varscan2
- GTSE1 | c.1143G>T p.L381= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV71889661; called by muse, mutect2, varscan2
- HPSE2 | c.1254G>C p.V418= | Silent (SNP) | VAF 57/180 reads (32%) | catalogued as COSV65179373; called by muse, varscan2
- ING1 | c.1005C>T p.A335= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV58171433; called by muse, mutect2, varscan2
- IQCB1 | c.174C>T p.L58= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV60437199; called by muse, mutect2, varscan2
- ITLN1 | c.768C>A p.V256= | Silent (SNP) | VAF 52/153 reads (34%) | catalogued as COSV58276526; called by muse, mutect2, varscan2
- KCNJ2 | c.18C>A p.T6= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV54663450; called by muse, mutect2, varscan2
- KRT6A | c.738G>A p.V246= | Silent (SNP) | VAF 43/89 reads (48%) | catalogued as rs755878651, COSV58104680, COSV58107299; called by muse, mutect2, varscan2
- LCT | c.4449C>T p.A1483= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs1402819408, COSV51556047; called by muse, mutect2, varscan2
- LRP1B | c.7632G>T p.L2544= | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as COSV67263387; called by muse, mutect2, varscan2
- MARS2 | c.801G>T p.P267= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV56572213; called by muse, mutect2, varscan2
- MCTP2 | c.186C>T p.A62= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV59149248; called by muse, mutect2, varscan2
- NHLRC2 | c.600C>T p.D200= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV65175821; called by muse, mutect2, varscan2
- OR2L13 | c.372C>A p.A124= | Silent (SNP) | VAF 65/360 reads (18%) | catalogued as COSV63559321; called by muse, mutect2, varscan2
- OR51A7 | c.768C>A p.T256= | Silent (SNP) | VAF 102/223 reads (46%) | catalogued as COSV63788865; called by muse, mutect2, varscan2
- OR6N1 | c.429G>A p.E143= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV58650110; called by muse, mutect2, varscan2
- PAX3 | c.381C>A p.G127= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV51343135; called by muse, mutect2, varscan2
- PCDHGB5 | c.951G>T p.G317= | Silent (SNP) | VAF 73/176 reads (41%) | catalogued as COSV54013497, COSV54018335; called by muse, mutect2, varscan2
- PDS5B | c.783G>A p.E261= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs1367650525, COSV59732951; called by muse, mutect2, varscan2
- PIK3R1 | c.603C>T p.A201= | Silent (SNP) | VAF 48/110 reads (44%) | catalogued as rs780278854, COSV57137229; called by muse, mutect2, varscan2
- RBL2 | c.3120A>T p.V1040= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV50885856; called by muse, mutect2
- RBM46 | c.1368G>A p.K456= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV55981390; called by muse, mutect2
- RYR3 | c.13701A>G p.A4567= (on ENST00000389232; = p.A4568= on NM_001036.6) | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV66805359; called by muse, mutect2, varscan2
- SALL1 | c.2541C>T p.S847= | Silent (SNP) | VAF 68/141 reads (48%) | catalogued as COSV51763222; called by muse, mutect2, varscan2
- SEZ6L | c.2448C>A p.T816= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV50680149; called by muse, mutect2, varscan2
- SLC12A5 | c.2733C>A p.V911= (on ENST00000454036 / NM_001134771.2; = p.V888= on NM_020708.5) | Silent (SNP) | VAF 56/169 reads (33%) | catalogued as COSV54800268, COSV54801409; called by muse, mutect2, varscan2
- SLC18A2 | c.549C>A p.A183= | Silent (SNP) | VAF 63/182 reads (35%) | catalogued as COSV100041465; called by muse, mutect2, varscan2
- SLC5A3 | c.1593T>A p.L531= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV62972760; called by muse, mutect2, varscan2
- SLC9A1 | c.96C>G p.L32= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV56055928; called by muse, mutect2, varscan2
- SNX7 | c.435G>A p.K145= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV60265887; called by muse, mutect2, varscan2
- STON2 | c.2076C>A p.T692= (on ENST00000649389 / NM_001366849.2; = p.T635= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV50852136; called by muse, mutect2, varscan2
- SYNE1 | c.24159G>C p.L8053= (on ENST00000367255 / NM_182961.4; = p.L7982= on NM_033071.3) | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV55075603; called by muse, mutect2, varscan2
- SYT8 | c.1125C>T p.P375= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs765027292, COSV53290837; called by muse, mutect2, varscan2
- TRPM6 | c.966G>T p.A322= | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as COSV62520457; called by muse, mutect2, varscan2
- TTN | c.100374T>A p.S33458= (on ENST00000591111; = p.S26034= on NM_003319.4) | Silent (SNP) | VAF 62/137 reads (45%) | catalogued as COSV60284272; called by muse, mutect2, varscan2
- WIPF1 | c.472A>C p.R158= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV55819432; called by muse, mutect2, varscan2
- WNT7A | c.576G>A p.L192= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs1396322737, COSV53201527; called by muse, mutect2, varscan2
- ZIC4 | c.981G>C p.A327= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs753763075, COSV67173668; called by muse, mutect2, varscan2
- ZNF536 | c.3855C>T p.S1285= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as COSV62832241, COSV62837710; called by muse, mutect2, varscan2
- ATP11A | c.*75A>T | 3'UTR (SNP) | VAF 29/80 reads (36%) | catalogued as COSV99367844; called by muse, mutect2, varscan2
- CFAP43 | c.417-4402G>T | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99530521; called by muse, mutect2, varscan2
- FBLN1 | c.1698-9575G>A | Intron (SNP) | VAF 17/41 reads (41%) | catalogued as COSV53047173; called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516179 A>G | 5'Flank (SNP) | VAF 4/50 reads (8%) | catalogued as COSV53064913; called by muse, mutect2
- PTPRN2 | c.2783+2263T>A | Intron (SNP) | VAF 8/102 reads (8%) | catalogued as COSV66104951; called by muse, mutect2
- RN7SL484P | chr15:99791002 G>T | 5'Flank (SNP) | VAF 50/186 reads (27%) | called by muse, mutect2
- RN7SL484P | chr15:99791003 C>A | 5'Flank (SNP) | VAF 49/185 reads (26%) | called by muse, mutect2
- SNORD114-1 | n.16G>A | RNA (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
